FM case AD13883 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Pancreas.
https://portal.gdc.cancer.gov/cases/e1ea305a-2a12-4aa2-b723-f5d48a32ccf6

Male, 52.1 years: Neuroendocrine carcinoma, NOS (ICD-O-3 8246/3) of the pancreas. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Tumor.
